Somatic mutation profile of tumor specimen TARGET-30-PARKAG-01A (aliquot TARGET-30-PARKAG-01A-01D) from TARGET case TARGET-30-PARKAG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.7 years (1,363 days).
Specimen TARGET-30-PARKAG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d49f9af1-fd39-4fb3-a12f-204fc0327041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARKAG-14A (Bone Marrow Normal), aliquot TARGET-30-PARKAG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8cd827b-abb1-44aa-9116-311c99cfc756

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 4, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV58613404; called by muse, mutect2, varscan2
- ARHGAP35 | c.3301G>T p.E1101* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV68329318; called by muse, mutect2, varscan2
- C2CD3 | c.4197G>A p.M1399I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV58089819; called by muse, mutect2, varscan2
- CXXC4 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV67296789; called by muse, mutect2, varscan2
- ENOX1 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV54888187; called by muse, mutect2, varscan2
- ERBB3 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV57247380; called by muse, mutect2, varscan2
- FLG | c.6385T>G p.S2129A | Missense Mutation (SNP) | VAF 123/590 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64239436; called by muse, varscan2
- GAD2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV99393789; called by muse, mutect2
- HSD11B1 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54829171; called by muse, mutect2, varscan2
- KCNH4 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs370501052; called by muse, mutect2, varscan2
- KIAA0319 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV65496494; called by muse, mutect2, varscan2
- LPAR4 | c.258G>T p.L86F | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV70912239; called by muse, mutect2, varscan2
- LRP2 | c.2251C>A p.Q751K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs758682329, COSV55541817; called by muse, mutect2, varscan2
- MYOM1 | c.3078C>A p.S1026R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55286065; called by muse, mutect2, varscan2
- NLRP9 | c.791dup p.M265Dfs*36 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | catalogued as rs745704129; called by mutect2, varscan2
- NOX1 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV54193470; called by muse, mutect2, varscan2
- OR12D3 | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV65830449; called by muse, mutect2
- OSBP | c.1922C>A p.A641D | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV55660981; called by muse, mutect2, varscan2
- PDE6G | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV58507040; called by muse, mutect2, varscan2
- PFKP | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66895055; called by muse, varscan2
- PHLDB1 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61876529; called by muse, mutect2
- PIF1 | c.951C>G p.D317E | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as COSV51421033; called by muse, mutect2, varscan2
- PLPP4 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64826741; called by muse, mutect2, varscan2
- PRSS23 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395497364, COSV54706323, COSV54707359; called by muse, mutect2, varscan2
- PVRIG | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1351386245, COSV52780390; called by muse, mutect2, varscan2
- QRICH2 | c.4086G>T p.W1362C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53151031; called by muse, mutect2, varscan2
- R3HDM1 | c.2687C>A p.A896D | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV51521065; called by muse, mutect2, varscan2
- RB1CC1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV50243273; called by muse, mutect2
- RPAP3 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.196); catalogued as COSV50041341; called by muse, mutect2, varscan2
- SLC25A12 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55531625; called by muse, mutect2, varscan2
- STRADB | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as COSV52042707; called by muse, mutect2, varscan2
- TTLL6 | c.1378C>A p.Q460K (on ENST00000393382 / NM_001130918.3; = p.Q153K on NM_173623.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as COSV64976230; called by muse, mutect2
- VANGL1 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59619458, COSV59620737; called by muse, mutect2, varscan2
- VWA5A | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64411898; called by muse, mutect2, varscan2
- WDR48 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs762161599, COSV56530431; called by muse, varscan2
- WDR81 | c.4238G>T p.G1413V (on ENST00000409644 / NM_001163809.2; = p.G362V on NM_152348.4) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373586101, COSV58487188; called by muse, mutect2, varscan2
- COL4A5 | c.1452C>A p.C484* | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- FAM47A | c.2258T>A p.I753N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FBXO42 | c.598del p.L200Yfs*25 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- TAS2R31 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2
- CD48 | c.132C>T p.N44= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1284507615, COSV63567164, COSV63567533; called by muse, mutect2, varscan2
- FAM47A | c.2259C>A p.I753= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- FAM71A | c.438C>A p.G146= | Silent (SNP) | VAF 65/201 reads (32%) | catalogued as COSV54236841; called by muse, mutect2, varscan2
- FOLR3 | c.31C>T p.L11= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as COSV61530740; called by muse, mutect2, varscan2
- MUC17 | c.3648A>G p.E1216= | Silent (SNP) | VAF 163/659 reads (25%) | catalogued as COSV60299851; called by muse, mutect2, varscan2
- NES | c.4455G>A p.L1485= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs562420767, COSV63962462; called by muse, mutect2, varscan2
- PCDHGA10 | c.2094G>A p.V698= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as COSV54010397; called by muse, varscan2
- TBX19 | c.1092A>T p.G364= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV63198215; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16518C>A | Intron (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
